Somatic mutation profile of cancer-model specimen HCM-BROD-0253-C15-85B (3D Organoid, passage 4; aliquot HCM-BROD-0253-C15-85B-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0253-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 77.3 years (28,216 days).
Specimen HCM-BROD-0253-C15-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf47f4a0-6a62-4a9d-b5fb-83a32e6d80db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0253-C15-10B (Blood Derived Normal), aliquot HCM-BROD-0253-C15-10B-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca312fff-8a19-4a39-b6b6-78163f4a39e6

The open-access MAF lists 217 somatic variants for this specimen: 156 protein-altering or splice-affecting, 53 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 134, Silent 53, Nonsense Mutation 9, Frame Shift Ins 5, Intron 5, 5'Flank 3, Frame Shift Del 3, In Frame Del 2, Splice Region 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 293/293 reads (100%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABHD16A | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 133/337 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as COSV101013142; called by muse, mutect2, varscan2
- ADGRB1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 275/1027 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV60099983; called by muse, varscan2
- ADGRB2 | c.3620G>A p.R1207Q | Missense Mutation (SNP) | VAF 132/375 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs148580797; called by muse, mutect2, varscan2
- ADGRV1 | c.13323_13325dup p.S4442dup | In Frame Ins (INS) | VAF 157/427 reads (37%) | catalogued as CI122150; called by mutect2, pindel, varscan2
- ALX4 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 133/427 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs368050443; called by muse, mutect2, varscan2
- APC | c.4678G>T p.E1560* | Nonsense Mutation (SNP) | VAF 254/254 reads (100%) | catalogued as COSV57321415, COSV57331697; called by muse, mutect2, varscan2
- ARHGEF11 | c.1691A>G p.N564S | Missense Mutation (SNP) | VAF 104/339 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.406); catalogued as rs757106673; called by muse, mutect2, varscan2
- ARID1B | c.3492G>T p.K1164N | Missense Mutation (SNP) | VAF 232/312 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV51687018; called by muse, mutect2, varscan2
- BLID | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 101/385 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.534); catalogued as rs748261974; called by muse, mutect2, varscan2
- C5AR2 | c.761T>G p.L254R | Missense Mutation (SNP) | VAF 516/1073 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99953788; called by muse, mutect2, varscan2
- CCDC197 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 161/306 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs1487873714; called by muse, mutect2, varscan2
- CD1A | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 216/332 reads (65%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs139349958; called by muse, mutect2, varscan2
- CELSR1 | c.5000G>A p.R1667K | Missense Mutation (SNP) | VAF 173/337 reads (51%) | SIFT tolerated (0.83); PolyPhen benign (0.01); catalogued as rs755657180; called by muse, mutect2, varscan2
- COL2A1 | c.2463G>C p.P821= | Splice Region (SNP) | VAF 142/446 reads (32%) | catalogued as COSV61529827; called by muse, mutect2, varscan2
- CPSF1 | c.424C>T p.R142W | Missense Mutation (SNP) | VAF 205/842 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554866754, COSV100574308; called by muse, mutect2, varscan2
- CRAT | c.1867C>T p.R623W | Missense Mutation (SNP) | VAF 129/443 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs551012337; called by muse, mutect2, varscan2
- CYP8B1 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 376/546 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs371888894; called by muse, mutect2, varscan2
- DLX5 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 155/498 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV56032991, COSV99756767; called by muse, mutect2, varscan2
- DNAH1 | c.12227G>A p.S4076N | Missense Mutation (SNP) | VAF 159/484 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1179305489; called by muse, mutect2, varscan2
- DOT1L | c.4031C>T p.A1344V | Missense Mutation (SNP) | VAF 270/557 reads (48%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.005); catalogued as COSV67113676; called by muse, mutect2, varscan2
- DPYSL5 | c.568G>A p.V190I | Missense Mutation (SNP) | VAF 114/397 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs144366814; called by muse, varscan2
- DRGX | c.386A>C p.K129T | Missense Mutation (SNP) | VAF 167/507 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.494); catalogued as COSV65136047; called by muse, mutect2, varscan2
- EDEM3 | c.1033C>T p.R345W | Missense Mutation (SNP) | VAF 174/495 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433584115, COSV58923268; called by muse, mutect2, varscan2
- GABRR1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 150/269 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs147057564; called by muse, mutect2, varscan2
- GALP | c.182C>G p.T61R | Missense Mutation (SNP) | VAF 279/546 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV61999965; called by muse, varscan2
- GCC2 | c.3854C>T p.A1285V | Missense Mutation (SNP) | VAF 215/358 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs147550431; called by muse, mutect2, varscan2
- GREB1 | c.2771C>T p.T924M | Missense Mutation (SNP) | VAF 414/637 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs755805775, COSV52191366; called by muse, mutect2, varscan2
- GRIN3A | c.1219C>T p.Q407* | Nonsense Mutation (SNP) | VAF 155/452 reads (34%) | catalogued as rs867982954; called by muse, mutect2, varscan2
- GRM4 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 176/543 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.042); catalogued as rs755343518, COSV65210097; called by muse, mutect2, varscan2
- KCND3 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 182/612 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56186607; called by muse, mutect2, varscan2
- KCNG1 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 213/974 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857093; called by muse, varscan2
- KDM3A | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 89/356 reads (25%) | catalogued as COSV57218679, COSV57224528; called by muse, mutect2, varscan2
- LRP10 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 489/490 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs758627607; called by muse, mutect2, varscan2
- MSH2 | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 130/440 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755920849, CM016299, COSV99254309; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTNR1B | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 398/623 reads (64%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV57066071; called by muse, mutect2, varscan2
- MUC19 | c.898A>C p.S300R | Missense Mutation (SNP) | VAF 259/507 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV101072291; called by muse, mutect2, varscan2
- MYT1L | c.1804G>A p.V602M | Missense Mutation (SNP) | VAF 216/368 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1343803199, COSV67719119; called by muse, varscan2
- NAV3 | c.6307C>A p.L2103I (on ENST00000397909 / NM_001024383.2; = p.L2081I on NM_014903.6) | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99886388; called by muse, mutect2, varscan2
- PADI4 | c.374G>A p.G125D | Missense Mutation (SNP) | VAF 150/460 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1044788604; called by muse, mutect2, varscan2
- PGBD5 | c.1304C>T p.A435V (on ENST00000525115; = p.A504V on NM_001258311.2) | Missense Mutation (SNP) | VAF 143/470 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs1189651773; called by muse, varscan2
- PKHD1 | c.7718G>A p.R2573H | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs371730612; called by muse, mutect2, varscan2
- PKHD1 | c.4402C>A p.L1468I | Missense Mutation (SNP) | VAF 301/445 reads (68%) | SIFT tolerated (0.55); PolyPhen benign (0.024); catalogued as COSV61874342; called by muse, mutect2, varscan2
- PPP1R16A | c.1085G>C p.R362P | Missense Mutation (SNP) | VAF 1023/1024 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99477310; called by muse, mutect2, varscan2
- PRKAA2 | c.270dup p.M91Yfs*10 | Frame Shift Ins (INS) | VAF 68/213 reads (32%) | catalogued as rs776405656; called by mutect2, varscan2
- PSMD3 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 292/462 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52857355; called by muse, mutect2, varscan2
- PTPRM | c.3985C>T p.R1329C | Missense Mutation (SNP) | VAF 138/422 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761371811; called by muse, mutect2, varscan2
- PTPRZ1 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 90/288 reads (31%) | catalogued as COSV101100076; called by muse, mutect2, varscan2
- RASAL1 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 181/602 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs1369598149; called by muse, mutect2, varscan2
- RTKN | c.896G>A p.R299H (on ENST00000272430 / NM_001015055.2; = p.R286H on NM_033046.2) | Missense Mutation (SNP) | VAF 111/349 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376959473, COSV99269632; called by muse, mutect2, varscan2
- SERPINB7 | c.146A>G p.D49G | Missense Mutation (SNP) | VAF 128/404 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs754470058; called by muse, mutect2, varscan2
- SLC6A1 | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 259/396 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs372892801; called by muse, mutect2, varscan2
- SMARCA4 | c.3485G>A p.G1162D | Missense Mutation (SNP) | VAF 388/390 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60811919; called by muse, mutect2, varscan2
- SV2C | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 146/304 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs751358005, COSV100456517, COSV59215345; called by muse, mutect2, varscan2
- SYNE2 | c.16513C>T p.R5505W | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.586); catalogued as rs767970692, COSV59953844, COSV59957623; called by muse, mutect2
- SYTL2 | c.582G>A p.E194= | Splice Region (SNP) | VAF 69/233 reads (30%) | catalogued as rs748426504; called by muse, mutect2, varscan2
- TMEM132C | c.2383G>A p.V795I | Missense Mutation (SNP) | VAF 154/412 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs1052584163; called by muse, mutect2, varscan2
- TMEM200A | c.418T>C p.F140L | Missense Mutation (SNP) | VAF 134/399 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1264868900, COSV51661919; called by muse, mutect2, varscan2
- TRABD2B | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 271/849 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.139); catalogued as rs1048824037; called by muse, varscan2
- TTN | c.63467C>T p.P21156L (on ENST00000591111; = p.P13732L on NM_003319.4) | Missense Mutation (SNP) | VAF 302/604 reads (50%) | PolyPhen probably damaging (0.917); catalogued as rs1371471381, COSV100597244, COSV59869160; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5C | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 301/302 reads (100%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.959); catalogued as rs998293655; called by muse, mutect2, varscan2
- USP8 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 214/214 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs770207958; called by muse, mutect2, varscan2
- ZNF724 | c.738A>G p.I246M | Missense Mutation (SNP) | VAF 21/416 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.117); catalogued as COSV101370076; called by muse, mutect2
- ZNF729 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 162/243 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762673679; called by muse, mutect2, varscan2
- ZSCAN18 | c.1430C>T p.P477L | Missense Mutation (SNP) | VAF 234/948 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as rs1184585999; called by muse, mutect2, varscan2
- ABCA6 | c.4593C>A p.F1531L | Missense Mutation (SNP) | VAF 285/447 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA8 | c.4730C>T p.P1577L | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ACTBL2 | c.335dup p.N112Kfs*57 | Frame Shift Ins (INS) | VAF 139/378 reads (37%) | called by mutect2, pindel, varscan2
- ADCY6 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 524/843 reads (62%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRB3 | c.2491_2492del p.L831Gfs*9 | Frame Shift Del (DEL) | VAF 160/305 reads (52%) | called by mutect2, pindel, varscan2
- ARHGAP23 | c.3197G>A p.R1066K | Missense Mutation (SNP) | VAF 254/709 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BIRC6 | c.9742G>T p.V3248L | Missense Mutation (SNP) | VAF 129/426 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- CACNA1A | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 24/700 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); called by muse, mutect2
- CALD1 | c.29T>G p.L10R | Missense Mutation (SNP) | VAF 106/308 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC181 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 146/481 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC65 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 100/373 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CILP | c.2307G>C p.Q769H | Missense Mutation (SNP) | VAF 158/354 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNOT3 | c.2112_2136del p.M704Ifs*57 | Frame Shift Del (DEL) | VAF 197/700 reads (28%) | called by mutect2, pindel, varscan2
- CNTLN | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 310/310 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, varscan2
- COMP | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 248/503 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSTF2T | c.107T>G p.F36C | Missense Mutation (SNP) | VAF 119/411 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTBP2 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 118/288 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CUL4A | c.2204G>T p.R735I (on ENST00000375440 / NM_001008895.4; = p.R635I on NM_003589.3) | Missense Mutation (SNP) | VAF 108/232 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CYP21A2 | c.265T>G p.F89V | Missense Mutation (SNP) | VAF 77/379 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX27 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 156/731 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DIPK1A | c.543_569del p.D181_G189del | In Frame Del (DEL) | VAF 197/227 reads (87%) | called by mutect2, pindel, varscan2
- DNAH17 | c.6457G>A p.V2153I | Missense Mutation (SNP) | VAF 180/476 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- DNAJC12 | c.418C>G p.L140V | Missense Mutation (SNP) | VAF 168/522 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DOP1B | c.5068G>T p.A1690S | Missense Mutation (SNP) | VAF 135/556 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- DYSF | c.3500T>A p.M1167K | Missense Mutation (SNP) | VAF 267/402 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ERICH3 | c.309G>C p.R103S | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FBXO11 | c.991G>A p.V331I (on ENST00000403359 / NM_001190274.2; = p.V247I on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 178/293 reads (61%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- FGD1 | c.2308C>A p.R770S | Missense Mutation (SNP) | VAF 26/534 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.154); called by muse, mutect2
- FHDC1 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 285/287 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- FKBPL | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 273/862 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLNA | c.6841G>T p.A2281S (on ENST00000369850 / NM_001110556.2; = p.A2273S on NM_001456.3) | Missense Mutation (SNP) | VAF 238/455 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- FLRT2 | c.719A>T p.N240I | Missense Mutation (SNP) | VAF 162/328 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GABRE | c.723G>T p.K241N | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GAPVD1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 155/458 reads (34%) | called by muse, mutect2, varscan2
- GML | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 110/459 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- H6PD | c.450A>C p.E150D | Missense Mutation (SNP) | VAF 159/569 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- HIVEP2 | c.3460G>C p.A1154P | Missense Mutation (SNP) | VAF 144/490 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- HOXD3 | c.875T>C p.L292P | Missense Mutation (SNP) | VAF 223/940 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- IGFN1 | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.232A>G p.S78G | Missense Mutation (SNP) | VAF 150/886 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IL1RAPL1 | c.22T>G p.L8V | Missense Mutation (SNP) | VAF 248/249 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- IRS2 | c.1574C>A p.A525E | Missense Mutation (SNP) | VAF 657/657 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ITIH4 | c.1940G>A p.W647* | Nonsense Mutation (SNP) | VAF 285/460 reads (62%) | called by muse, mutect2, varscan2
- KDM3B | c.2832G>T p.R944S | Missense Mutation (SNP) | VAF 87/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF14 | c.2816T>G p.L939R | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIF5C | c.2082G>T p.Q694H | Missense Mutation (SNP) | VAF 141/624 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- LAMA4 | c.1352A>G p.Y451C (on ENST00000230538 / NM_001105206.3; = p.Y444C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- MAP3K15 | c.2285A>C p.K762T | Missense Mutation (SNP) | VAF 85/218 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MED15 | c.2341C>A p.H781N (on ENST00000263205 / NM_001003891.3; = p.H741N on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 198/826 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- MTOR | c.6578G>A p.R2193H | Missense Mutation (SNP) | VAF 155/443 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUL1 | c.305T>G p.V102G | Missense Mutation (SNP) | VAF 246/378 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYBPC2 | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 141/613 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYT1L | c.1630A>G p.S544G | Missense Mutation (SNP) | VAF 235/393 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- NBPF4 | c.1756G>T p.V586F | Missense Mutation (SNP) | VAF 112/442 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- NES | c.1684A>C p.N562H | Missense Mutation (SNP) | VAF 320/474 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, varscan2
- NUP205 | c.5549A>G p.E1850G | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- P3H4 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 177/668 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PEG3 | c.1475T>C p.V492A | Missense Mutation (SNP) | VAF 133/647 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- PIGM | c.557dup p.Y186* | Nonsense Mutation (INS) | VAF 127/490 reads (26%) | called by mutect2, pindel, varscan2
- PIP4K2A | c.1184A>G p.K395R | Missense Mutation (SNP) | VAF 306/475 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PLOD1 | c.1225A>G p.T409A | Missense Mutation (SNP) | VAF 132/416 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PSD4 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 460/726 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PSMD3 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 289/926 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RB1CC1 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 140/568 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- REG3G | c.454A>C p.S152R | Missense Mutation (SNP) | VAF 123/357 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- RYR2 | c.13270G>T p.A4424S | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.028); called by muse, varscan2
- SDC2 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 450/452 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- SETD2 | c.6899_6900insAT p.T2301* | Frame Shift Ins (INS) | VAF 244/472 reads (52%) | called by mutect2, pindel, varscan2
- SKOR2 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 52/510 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- SLC13A1 | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 284/284 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SLC1A5 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 394/807 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC34A3 | c.1776G>T p.E592D | Missense Mutation (SNP) | VAF 331/502 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPDL1 | c.1382C>A p.T461N | Missense Mutation (SNP) | VAF 346/513 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTA1 | c.4064T>G p.L1355R | Missense Mutation (SNP) | VAF 151/458 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SUSD5 | c.444C>G p.H148Q | Missense Mutation (SNP) | VAF 136/528 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TAFA3 | c.265G>A p.A89T | Missense Mutation (SNP) | VAF 129/465 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TAS2R31 | c.897C>A p.Y299* | Nonsense Mutation (SNP) | VAF 233/630 reads (37%) | called by muse, varscan2
- TDRD6 | c.4118_4119dup p.I1374* | Frame Shift Ins (INS) | VAF 125/405 reads (31%) | called by mutect2, pindel, varscan2
- TIPARP | c.1970T>C p.I657T | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- TMEM132D | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 174/564 reads (31%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- TRNAU1AP | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 302/485 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- TRPA1 | c.161del p.K54Rfs*3 | Frame Shift Del (DEL) | VAF 106/420 reads (25%) | called by mutect2, pindel*, varscan2
- ZFYVE9 | c.4166T>C p.M1389T | Missense Mutation (SNP) | VAF 257/408 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, varscan2
- ZMYM2 | c.2699A>G p.Y900C | Missense Mutation (SNP) | VAF 250/250 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF12 | c.2023_2025del p.A675del (on ENST00000405858 / NM_016265.4; = p.A637del on NM_006956.3) | In Frame Del (DEL) | VAF 104/415 reads (25%) | called by mutect2, pindel, varscan2
- ZNF283 | c.1259A>G p.Q420R | Missense Mutation (SNP) | VAF 292/588 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF362 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 161/468 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ZNF407 | c.3910G>T p.G1304W | Missense Mutation (SNP) | VAF 126/440 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.047); called by mutect2, varscan2
- ZNF714 | c.538_539insC p.K180Tfs*4 | Frame Shift Ins (INS) | VAF 142/1176 reads (12%) | called by mutect2, pindel, varscan2
- ZNF831 | c.2576A>G p.D859G | Missense Mutation (SNP) | VAF 568/570 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, varscan2
- ZP2 | c.1172T>C p.L391P | Missense Mutation (SNP) | VAF 146/308 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABI3BP | c.1581C>T p.P527= | Silent (SNP) | VAF 63/250 reads (25%) | called by muse, mutect2, varscan2
- ACAP3 | c.1932G>A p.E644= | Silent (SNP) | VAF 84/823 reads (10%) | catalogued as rs1399057907; called by muse, mutect2
- ANK3 | c.7554C>A p.I2518= | Silent (SNP) | VAF 158/470 reads (34%) | called by mutect2, varscan2
- ATAD3A | c.1764G>A p.T588= | Silent (SNP) | VAF 107/291 reads (37%) | catalogued as rs775376698, COSV59235496; called by muse, mutect2, varscan2
- ATE1 | c.1050C>A p.I350= | Silent (SNP) | VAF 146/334 reads (44%) | catalogued as COSV56436354; called by muse, mutect2, varscan2
- BCAN | c.1425G>A p.E475= | Silent (SNP) | VAF 157/540 reads (29%) | called by muse, mutect2, varscan2
- BCR | c.1122G>A p.S374= | Silent (SNP) | VAF 261/523 reads (50%) | catalogued as COSV59934048; called by muse, mutect2, varscan2
- C16orf72 | c.564G>T p.R188= | Silent (SNP) | VAF 135/270 reads (50%) | called by muse, mutect2, varscan2
- CFAP44 | c.4191G>A p.Q1397= | Silent (SNP) | VAF 111/362 reads (31%) | called by muse, mutect2, varscan2
- CHRNA4 | c.180C>T p.D60= | Silent (SNP) | VAF 192/551 reads (35%) | catalogued as rs112051150, COSV64717356, COSV64717701; called by muse, mutect2, varscan2
- CORO1B | c.1197C>T p.S399= | Silent (SNP) | VAF 294/921 reads (32%) | called by muse, mutect2, varscan2
- CPNE1 | c.195G>A p.E65= (on ENST00000352393; = p.E70= on NM_003915.5) | Silent (SNP) | VAF 116/1043 reads (11%) | catalogued as rs146302278, COSV58290454; called by muse, mutect2, varscan2
- DENND3 | c.369G>A p.K123= | Silent (SNP) | VAF 125/606 reads (21%) | called by muse, mutect2, varscan2
- DPP6 | c.132C>T p.L44= | Silent (SNP) | VAF 73/184 reads (40%) | catalogued as rs866677381; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1551G>A p.K517= (on ENST00000361735 / NM_015935.5; = p.K431= on NM_014955.3) | Silent (SNP) | VAF 141/443 reads (32%) | called by muse, mutect2, varscan2
- EGFLAM | c.1542C>T p.G514= | Silent (SNP) | VAF 134/378 reads (35%) | catalogued as rs757246458, COSV59297441; called by muse, mutect2, varscan2
- EPC2 | c.1236T>C p.R412= | Silent (SNP) | VAF 12/406 reads (3%) | called by muse, mutect2
- FMN2 | c.3144C>T p.P1048= | Silent (SNP) | VAF 60/338 reads (18%) | called by muse, mutect2, varscan2
- FMN2 | c.3513G>A p.A1171= | Silent (SNP) | VAF 85/333 reads (26%) | catalogued as rs775315994; called by muse, mutect2, varscan2
- FRY | c.1806A>T p.I602= | Silent (SNP) | VAF 96/223 reads (43%) | called by muse, mutect2, varscan2
- GABBR1 | c.2661G>A p.K887= | Silent (SNP) | VAF 392/630 reads (62%) | called by muse, varscan2
- GLI3 | c.528C>A p.I176= | Silent (SNP) | VAF 379/379 reads (100%) | called by muse, varscan2
- GNAQ | c.66C>T p.N22= | Silent (SNP) | VAF 83/871 reads (10%) | called by muse, mutect2
- IL10RA | c.705C>T p.N235= | Silent (SNP) | VAF 115/400 reads (29%) | catalogued as rs752280029, COSV57141275; called by muse, mutect2, varscan2
- IMPG1 | c.915G>A p.T305= | Silent (SNP) | VAF 126/352 reads (36%) | catalogued as rs144378004; called by muse, mutect2, varscan2
- INTS11 | c.618C>T p.Y206= | Silent (SNP) | VAF 314/483 reads (65%) | catalogued as rs761287688; called by muse, mutect2, varscan2
- ITGA5 | c.1479G>A p.V493= | Silent (SNP) | VAF 162/606 reads (27%) | called by muse, mutect2, varscan2
- KLHL38 | c.1578G>A p.T526= | Silent (SNP) | VAF 215/906 reads (24%) | catalogued as rs777529886; called by muse, mutect2, varscan2
- L1CAM | c.1587G>A p.E529= | Silent (SNP) | VAF 56/618 reads (9%) | called by muse, mutect2
- LIN37 | c.426G>A p.P142= | Silent (SNP) | VAF 118/612 reads (19%) | catalogued as rs1283377672, COSV99137444; called by muse, mutect2, varscan2
- LRRC4C | c.1863G>A p.V621= | Silent (SNP) | VAF 108/332 reads (33%) | catalogued as rs771871840; called by muse, varscan2
- MAMDC4 | c.3234C>A p.G1078= (on ENST00000445819; = p.G999= on NM_206920.3) | Silent (SNP) | VAF 357/548 reads (65%) | catalogued as COSV56376368; called by muse, mutect2, varscan2
- MARCHF1 | c.507G>A p.V169= (on ENST00000274056; = p.V152= on NM_017923.4) | Silent (SNP) | VAF 234/234 reads (100%) | catalogued as COSV56815456; called by muse, mutect2, varscan2
- MRE11 | c.2112A>G p.R704= (on ENST00000323929 / NM_005591.4; = p.R676= on NM_005590.4) | Silent (SNP) | VAF 60/203 reads (30%) | called by muse, mutect2, varscan2
- MTX1 | c.780T>G p.T260= | Silent (SNP) | VAF 139/399 reads (35%) | called by muse, mutect2, varscan2
- MYO1C | c.2952G>A p.A984= (on ENST00000648651 / NM_001080779.2; = p.A949= on NM_033375.5) | Silent (SNP) | VAF 151/151 reads (100%) | catalogued as rs752092495; called by muse, mutect2, varscan2
- MYRF | c.915G>A p.P305= (on ENST00000278836 / NM_001127392.3; = p.P296= on NM_013279.4) | Silent (SNP) | VAF 588/875 reads (67%) | catalogued as rs778037643, COSV53892387; called by muse, mutect2, varscan2
- NAALADL2 | c.1206G>A p.A402= | Silent (SNP) | VAF 97/318 reads (31%) | catalogued as rs772833242, COSV69158740; called by muse, mutect2, varscan2
- NAB1 | c.279C>T p.S93= | Silent (SNP) | VAF 280/580 reads (48%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.1605G>A p.S535= | Silent (SNP) | VAF 478/693 reads (69%) | called by muse, mutect2, varscan2
- PIWIL3 | c.1288A>C p.R430= | Silent (SNP) | VAF 44/322 reads (14%) | called by muse, mutect2, varscan2
- PKD1L3 | c.1071C>A p.P357= | Silent (SNP) | VAF 146/347 reads (42%) | called by muse, mutect2, varscan2
- POLR3A | c.2007A>G p.R669= | Silent (SNP) | VAF 146/538 reads (27%) | called by muse, mutect2, varscan2
- PRAME | c.855C>T p.I285= | Silent (SNP) | VAF 126/529 reads (24%) | catalogued as rs758741634, COSV67162663; called by muse, mutect2, varscan2
- RASA3 | c.1188G>A p.L396= | Silent (SNP) | VAF 261/261 reads (100%) | called by muse, mutect2, varscan2
- SLC18B1 | c.726C>T p.F242= | Silent (SNP) | VAF 233/368 reads (63%) | catalogued as rs371507856; called by muse, mutect2, varscan2
- SLC22A16 | c.1701G>A p.A567= | Silent (SNP) | VAF 110/341 reads (32%) | catalogued as rs748989233, COSV57926911; called by muse, mutect2, varscan2
- SLC35D2 | c.51C>T p.G17= | Silent (SNP) | VAF 149/384 reads (39%) | catalogued as rs1230145296; called by muse, mutect2, varscan2
- VASN | c.1176G>A p.P392= | Silent (SNP) | VAF 311/671 reads (46%) | catalogued as rs541520542; called by muse, mutect2, varscan2
- VPS13B | c.10386C>T p.S3462= | Silent (SNP) | VAF 158/661 reads (24%) | called by muse, mutect2, varscan2
- WBP1 | c.123T>G p.G41= | Silent (SNP) | VAF 152/460 reads (33%) | called by muse, mutect2, varscan2
- WNT6 | c.321C>T p.F107= | Silent (SNP) | VAF 180/526 reads (34%) | called by muse, varscan2
- ZMAT3 | c.432G>C p.T144= | Silent (SNP) | VAF 103/318 reads (32%) | called by muse, varscan2
- C2orf16 | chr2:27575977 C>A | 5'Flank (SNP) | VAF 167/472 reads (35%) | called by muse, varscan2
- C2orf16 | chr2:27575978 T>C | 5'Flank (SNP) | VAF 179/501 reads (36%) | called by muse, mutect2, varscan2
- HHIP | c.831+104T>A | Intron (SNP) | VAF 56/139 reads (40%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+17681G>A | Intron (SNP) | VAF 128/433 reads (30%) | called by muse, mutect2, varscan2
- PSD3 | c.2176-28219C>T | Intron (SNP) | VAF 108/204 reads (53%) | called by muse, varscan2
- RSPH9 | c.671-4331G>T | Intron (SNP) | VAF 136/386 reads (35%) | called by muse, mutect2, varscan2
- TARM1 | chr19:54081328 G>T | 5'Flank (SNP) | VAF 28/816 reads (3%) | catalogued as COSV71524926; called by muse, mutect2
- TTN | c.10360+1626C>A | Intron (SNP) | VAF 129/615 reads (21%) | called by muse, mutect2, varscan2
